Somatic mutation profile of tumor specimen MP2PRT-PARCWJ-TMP1-A (aliquot MP2PRT-PARCWJ-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARCWJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,092 days).
Specimen MP2PRT-PARCWJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77c16021-c655-4bdc-8b3e-77c28f2de17c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARCWJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARCWJ-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1227e87c-41f6-42ea-8b1a-4f169ece5644

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QC | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 171/369 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224349185; called by muse, mutect2, varscan2
- MUC5AC | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 89/386 reads (23%) | SIFT tolerated (0.07); catalogued as rs755939669; called by muse, mutect2, varscan2
- OBSCN | c.20678G>A p.R6893Q | Missense Mutation (SNP) | VAF 70/620 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs994223032; called by muse, mutect2, varscan2
- PPP2R3B | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV66813185; called by muse, mutect2, varscan2
- FAM83B | c.1185A>C p.E395D | Missense Mutation (SNP) | VAF 137/259 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TNN | c.1487C>T p.T496I | Missense Mutation (SNP) | VAF 179/386 reads (46%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- VWA5B1 | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
